Somatic mutation profile of tumor specimen C3N-01361-01 (aliquot CPT0088760009) from CPTAC case C3N-01361, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 48.1 years (17,562 days).
Specimen C3N-01361-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11863bb8-a990-401b-93a9-6ea81fcb1810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01361-31 (Blood Derived Normal), aliquot CPT0088820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff56a87-2c18-4c7f-bea7-489ba6be53e0

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Frame Shift Del 3, Intron 2, RNA 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCIN | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs1447888896; called by muse, mutect2, varscan2
- CHRM2 | c.1209C>A p.Y403* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as rs749588890; called by muse, mutect2
- CHRM2 | c.1211A>T p.N404I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57765827; called by muse, mutect2
- FBN2 | c.7840+1G>A p.X2614_splice | Splice Site (SNP) | VAF 69/602 reads (11%) | catalogued as rs746742193; called by muse, varscan2
- MCCD1 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV66019755; called by muse, mutect2, varscan2
- MFN2 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs747733583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHLPP2 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); catalogued as rs774406482; called by muse, mutect2, varscan2
- PLAUR | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV55391418; called by muse, mutect2, varscan2
- PPP1R16A | c.685dup p.L229Pfs*33 | Frame Shift Ins (INS) | VAF 9/78 reads (12%) | catalogued as rs1315376411; called by mutect2, pindel
- VHL | c.291del p.Y98Tfs*61 | Frame Shift Del (DEL) | VAF 134/412 reads (33%) | catalogued as COSV56554961; called by mutect2, pindel, varscan2
- ACACA | c.2703G>A p.M901I | Missense Mutation (SNP) | VAF 68/415 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CCDC93 | c.1225del p.E409Rfs*3 | Frame Shift Del (DEL) | VAF 32/191 reads (17%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.4170T>G p.D1390E (on ENST00000651564; = p.D1343E on NM_015692.5) | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DUSP12 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FAM214A | c.1231G>T p.V411F | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PLCD4 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POU4F3 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 126/344 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS1 | c.2812T>A p.L938I | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SWAP70 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SYN1 | c.661A>T p.N221Y | Missense Mutation (SNP) | VAF 103/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNKS2 | c.2780T>A p.I927N | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TRPM5 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- TRRAP | c.5576G>A p.R1859H (on ENST00000359863 / NM_001244580.1; = p.R1841H on NM_003496.3) | Missense Mutation (SNP) | VAF 17/431 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- USP34 | c.7159G>C p.V2387L | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZHX3 | c.1941T>G p.S647R | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ZSCAN23 | c.627del p.I210Yfs*32 | Frame Shift Del (DEL) | VAF 27/134 reads (20%) | called by mutect2, pindel, varscan2
- CCIN | c.546C>G p.R182= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as COSV58725684; called by muse, mutect2, varscan2
- IL6 | c.177C>T p.Y59= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- NEK1 | c.2604T>C p.S868= | Silent (SNP) | VAF 44/198 reads (22%) | called by muse, mutect2, varscan2
- NID2 | c.3591C>T p.R1197= | Silent (SNP) | VAF 38/209 reads (18%) | catalogued as rs367692141; called by muse, mutect2, varscan2
- PHLPP1 | c.660C>T p.L220= | Silent (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- POM121C | c.3222A>G p.P1074= (on ENST00000607367; = p.P832= on NM_001099415.3) | Silent (SNP) | VAF 32/234 reads (14%) | catalogued as rs1344813743; called by muse, mutect2, varscan2
- TP53BP1 | c.5493C>T p.V1831= | Silent (SNP) | VAF 76/405 reads (19%) | called by muse, mutect2, varscan2
- TSFM | c.774G>A p.L258= (on ENST00000323833 / NM_001172696.2; = p.L237= on NM_005726.6) | Silent (SNP) | VAF 37/260 reads (14%) | called by muse, mutect2, varscan2
- ZNF75D | c.807G>A p.E269= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- ADIRF | c.-30T>A | 5'UTR (SNP) | VAF 34/180 reads (19%) | called by muse, varscan2
- C8orf44-SGK3 | c.-121-25989T>A | Intron (SNP) | VAF 47/288 reads (16%) | called by muse, mutect2, varscan2
- LINC02272 | n.284C>G | RNA (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5434-42G>T | Intron (SNP) | VAF 33/167 reads (20%) | called by muse, mutect2, varscan2
